Somatic mutation profile of tumor specimen TCGA-F5-6465-01A (aliquot TCGA-F5-6465-01A-11D-1733-10) from TCGA case TCGA-F5-6465, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.2 years (23,432 days).
Specimen TCGA-F5-6465-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5041130f-09a6-4f2e-94ce-704a144118b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6465-10A (Blood Derived Normal), aliquot TCGA-F5-6465-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91bcfbd6-3028-43cc-993d-e4bf289d1c97

The open-access MAF lists 111 somatic variants for this specimen: 88 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 21, Nonsense Mutation 7, Splice Site 5, Frame Shift Del 3, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.2797C>T p.R933* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs570388861, CM060771, COSV56848170; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 41/177 reads (23%) | catalogued as rs121913462, CM077502, COSV57322511, COSV57366061, COSV57375983; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 44/131 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2
- ABCA6 | c.3436T>G p.L1146V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV52643913; called by muse, mutect2, varscan2
- ADAM30 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.285); catalogued as COSV65561959; called by muse, mutect2, varscan2
- AFF3 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1248729862, COSV57859704; called by muse, mutect2, varscan2
- APC | c.3493A>T p.K1165* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV57326930, COSV57341138; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1328C>G p.A443G | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV100771701; called by muse, mutect2
- ASH2L | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1434902156, COSV51700046; called by muse, mutect2, varscan2
- ATG4D | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.121); catalogued as rs752546576, COSV57265703; called by muse, mutect2, varscan2
- BOD1L1 | c.2703G>C p.K901N | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1560206042, COSV50048031; called by muse, mutect2, varscan2
- C1QTNF9B | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs756870424, COSV101158510; called by muse, mutect2, varscan2
- CLTC | c.2245A>G p.R749G | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52252273; called by muse, mutect2, varscan2
- CNGA3 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs370911601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A5 | c.3340G>A p.A1114T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV60369687; called by muse, mutect2, varscan2
- COL6A6 | c.2708G>A p.R903Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1313232339, COSV62024644; called by muse, mutect2, varscan2
- CRB1 | c.2606C>A p.T869K | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100957587; called by muse, mutect2, varscan2
- CTNND2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV58868041; called by muse, mutect2, varscan2
- CUL9 | c.5276G>A p.R1759Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as rs531967221, COSV52733518; called by muse, mutect2, varscan2
- CUX2 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55644993; called by muse, varscan2
- CYLC2 | c.870A>T p.K290N | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100872292; called by muse, mutect2, varscan2
- DDX4 | c.2097+1G>T p.X699_splice | Splice Site (SNP) | VAF 16/74 reads (22%) | catalogued as COSV61756845; called by muse, mutect2, varscan2
- DST | c.1930G>A p.V644I (on ENST00000361203 / NM_001374722.1; = p.V318I on NM_001723.6) | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV55035366; called by muse, mutect2, varscan2
- FBN3 | c.4576G>T p.A1526S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54470263; called by muse, mutect2, varscan2
- FCRL6 | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV58942380; called by muse, mutect2, varscan2
- FLRT3 | c.654C>G p.D218E | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.047); catalogued as COSV54040536; called by muse, mutect2, varscan2
- FREM2 | c.7785C>A p.F2595L | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV54849179; called by muse, mutect2, varscan2
- GABRG1 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs369652618; called by muse, mutect2, varscan2
- GCKR | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.152); catalogued as COSV53107786, COSV53109497; called by muse, mutect2, varscan2
- GLI3 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); catalogued as CD107046, COSV67893985; called by muse, mutect2, varscan2
- H2BC8 | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as rs202170052, COSV55127649; called by muse, mutect2, varscan2
- HNRNPDL | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as rs1051584744, COSV99786953; called by muse, mutect2
- INO80B | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as COSV51971357; called by muse, mutect2, varscan2
- KBTBD7 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV65267069; called by muse, mutect2, varscan2
- KLHL22 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.096); catalogued as COSV61022535; called by muse, mutect2, varscan2
- LEXM | c.505T>A p.Y169N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64023961; called by muse, mutect2, varscan2
- MAN2B2 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs771925392, COSV53456193; called by muse, mutect2, varscan2
- MAP9 | c.1842A>C p.E614D | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.851); catalogued as COSV60906120; called by muse, mutect2, varscan2
- MINPP1 | c.1106G>C p.G369A | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100916711; called by muse, mutect2, varscan2
- MRPL54 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.726); catalogued as rs1418732253, COSV57463590; called by muse, mutect2, varscan2
- MS4A6E | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.148); catalogued as rs955579804, COSV100279031; called by muse, mutect2, varscan2
- MSL3 | c.956C>T p.T319M (on ENST00000312196 / NM_078629.4; = p.T153M on NM_006800.4) | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1371447661, COSV56495522; called by muse, mutect2, varscan2
- NUMA1 | c.3497C>T p.T1166I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as COSV61190063; called by muse, mutect2, varscan2
- NUMA1 | c.3496A>C p.T1166P | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as COSV61190078; called by muse, mutect2, varscan2
- OPA1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as rs866025924, CD014021, COSV62482878; called by muse, mutect2, varscan2
- OR13C2 | c.622T>G p.L208V | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV73377778; called by muse, mutect2, varscan2
- OR14I1 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV61200640; called by muse, mutect2, varscan2
- OR2H1 | c.652G>C p.A218P | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.958); catalogued as COSV101009754; called by muse, mutect2, varscan2
- OR51I2 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58300102; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHA8 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.04); catalogued as COSV65339071; called by muse, mutect2, varscan2
- PDE11A | c.2256C>G p.I752M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53705904; called by muse, mutect2, varscan2
- PGAP6 | c.1351T>C p.W451R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV51742011; called by muse, mutect2, varscan2
- PHLDA1 | c.89T>A p.V30D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56998063; called by muse, mutect2, varscan2
- PNMA1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV54098116; called by muse, mutect2, varscan2
- POC1B | c.879+1G>C p.X293_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100543946; called by muse, mutect2, varscan2
- RALGAPA2 | c.4036C>A p.Q1346K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV52508679; called by muse, mutect2, varscan2
- RIC1 | c.1046+1G>A p.X349_splice | Splice Site (SNP) | VAF 50/218 reads (23%) | catalogued as COSV52607810; called by muse, mutect2, varscan2
- RNF145 | c.1048G>A p.V350I (on ENST00000424310 / NM_001199383.2; = p.V378I on NM_144726.2) | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.28); catalogued as rs778925094, COSV50864802; called by muse, mutect2, varscan2
- RNF213 | c.8875C>G p.L2959V | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100299290; called by muse, mutect2, varscan2
- RTP5 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.051); catalogued as rs773874422, COSV58321544; called by muse, mutect2
- SEMA3A | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs746887710, COSV54866315; called by muse, mutect2, varscan2
- SEMA3E | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as rs1042512907, COSV57090995; called by muse, mutect2, varscan2
- SIGLECL1 | c.387del p.F130Sfs*8 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | catalogued as COSV57062700, COSV57064410; called by mutect2, pindel, varscan2
- SLC25A39 | c.931C>T p.R311W (on ENST00000377095 / NM_001143780.3; = p.R303W on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs764855227, COSV56588933; called by muse, mutect2, varscan2
- SLC25A53 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 113/265 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs12863544, COSV62460539; called by muse, mutect2, varscan2
- SLCO2A1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs202244173, COSV60485749; called by muse, mutect2, varscan2
- SOHLH2 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV65901005, COSV65902572; called by muse, mutect2
- SPART | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.677); catalogued as rs1044806150, COSV62085279; called by muse, mutect2, varscan2
- SUPT20H | c.1329T>A p.D443E (on ENST00000350612 / NM_001014286.3; = p.D444E on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62249293; called by muse, mutect2, varscan2
- SYCP2 | c.2147G>C p.W716S | Missense Mutation (SNP) | VAF 97/621 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100698316, COSV62771749; called by muse, mutect2, varscan2
- SYT10 | c.1478C>T p.T493M | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs545012156, COSV57338661; called by muse, mutect2, varscan2
- TLR6 | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.06); catalogued as rs745501248, COSV67935686; called by muse, mutect2, varscan2
- TTN | c.25228G>A p.V8410I (on ENST00000591111; = p.V7483I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/174 reads (20%) | PolyPhen benign (0); catalogued as rs544958705, COSV59996011, COSV60134266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA1C | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as rs1428700785, COSV56511602; called by muse, mutect2, varscan2
- TUBA3C | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as rs867215111, COSV67139583; called by muse, mutect2, varscan2
- USP33 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs749373760, COSV62471156; called by muse, mutect2, varscan2
- VBP1 | c.524-1G>C p.X175_splice | Splice Site (SNP) | VAF 51/515 reads (10%) | catalogued as COSV53973619; called by muse, mutect2, varscan2
- WWC1 | c.2915G>A p.R972Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.736); catalogued as rs771485054, COSV54647201; called by muse, mutect2, varscan2
- ZBTB48 | c.1765C>T p.R589* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as rs764164145, COSV66552917; called by muse, mutect2, varscan2
- ZMAT1 | c.1755A>T p.R585S | Missense Mutation (SNP) | VAF 184/749 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV65659787; called by muse, mutect2, varscan2
- ZNF337 | c.88A>G p.S30G | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.874); catalogued as COSV53321601, COSV53322837; called by mutect2, varscan2
- IHH | c.865_899del p.R289Wfs*53 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | called by mutect2, pindel
- ITGA6 | c.1828-14_1837del p.X610_splice (on ENST00000442250; = p.X571_splice on NM_000210.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 40/137 reads (29%) | called by mutect2, pindel, varscan2
- PYGL | c.1934del p.F645Sfs*36 | Frame Shift Del (DEL) | VAF 31/149 reads (21%) | called by mutect2, pindel, varscan2
- SOX9 | c.610_611insAAG p.F204delins* | Nonsense Mutation (INS) | VAF 35/74 reads (47%) | called by mutect2, pindel*, varscan2
- SRCIN1 | c.732C>G p.I244M (on ENST00000621492; = p.I210M on NM_025248.3) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- AFDN | c.4521G>A p.S1507= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs963086126, COSV60054259; called by muse, mutect2, varscan2
- ANKRD22 | c.537A>G p.K179= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as COSV64237421; called by muse, mutect2, varscan2
- CACNA1E | c.4356C>T p.S1452= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs571237279, COSV62393227; called by muse, mutect2, varscan2
- CES3 | c.75A>G p.T25= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV57595093; called by muse, mutect2, varscan2
- CUL5 | c.1872A>G p.E624= | Silent (SNP) | VAF 37/161 reads (23%) | catalogued as COSV101263607; called by muse, mutect2, varscan2
- GIMAP6 | c.591C>T p.C197= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs561097678, COSV61032414; called by muse, mutect2, varscan2
- GNPTAB | c.1473G>A p.Q491= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV54780473; called by muse, mutect2
- KIF19 | c.2586G>T p.G862= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV63430415; called by muse, mutect2, varscan2
- MAMSTR | c.486A>C p.P162= (on ENST00000318083 / NM_001130915.2; = p.P59= on NM_182574.2) | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs769169827, COSV58883045; called by muse, varscan2
- MLST8 | c.486C>T p.N162= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs185180342, COSV57030914; called by muse, mutect2, varscan2
- MPPED2 | c.384A>C p.A128= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV63900726; called by muse, mutect2, varscan2
- OR5B2 | c.609T>C p.F203= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV56909381; called by muse, mutect2, varscan2
- PCDH17 | c.3214T>C p.L1072= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as rs1320589035, COSV64971461, COSV64971783, COSV64972529; called by muse, mutect2, varscan2
- PHIP | c.2949A>T p.I983= | Silent (SNP) | VAF 55/204 reads (27%) | catalogued as COSV99243093; called by muse, mutect2, varscan2
- RBP3 | c.1737G>A p.V579= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1555211294; called by muse, mutect2, varscan2
- SEPSECS | c.243C>T p.S81= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs1431335403, COSV57207279; called by muse, mutect2, varscan2
- TPH2 | c.135C>T p.D45= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs74510566, COSV61590555; called by muse, mutect2, varscan2
- TRPS1 | c.1830G>A p.S610= (on ENST00000220888 / NM_001330599.2; = p.S623= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/180 reads (50%) | catalogued as rs751550383, COSV55237292, COSV55246645; called by muse, mutect2, varscan2
- UBR7 | c.465C>T p.C155= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs567093314, COSV50150867; called by muse, mutect2, varscan2
- USP32 | c.474T>G p.T158= | Silent (SNP) | VAF 67/101 reads (66%) | catalogued as COSV56275947; called by muse, mutect2, varscan2
- ZNRF4 | c.81G>A p.A27= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs767884185, COSV55776043; called by muse, mutect2, varscan2
- VAX1 | chr10:117132297 T>G | 3'Flank (SNP) | VAF 21/79 reads (27%) | catalogued as COSV53330561; called by muse, mutect2, varscan2
- ZNF493 | c.-132+7917G>A | Intron (SNP) | VAF 30/103 reads (29%) | catalogued as rs181874152, COSV60551016; called by muse, mutect2, varscan2
